Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7686, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7686-01A (Primary Tumor).

Pathology Report for Subject [REDACTED]

Discussion: Numerous scattered MIB-1 reactive cells are identified with a labeling index of 6.6% calculated. Whereas this is relatively low for most anaplastic astrocytomas, it is fairly typical of gemistocytic tumors.

Microscopic Description: Sections demonstrate a moderately hypercellular glial neoplasm that is composed primarily of cells resembling atypical gemistocytes. Atypia ranges from mild to moderate with a few scattered highly atypical nuclei seen. There is no microvascular proliferation or necrosis. Only up to 2 mitoses per 10 high power fields are seen but some of the mitoses are atypical.

Diagnosis: Anaplastic Astrocytoma, gemistocytic.

MIB labeling index = 6.6%

Source: NCI Genomic Data Commons file 97ee85c6-108b-4d18-8451-606b3021427d (TCGA-HT-7686.1BE5B4DB-9B53-4B2F-B44B-1383788D473C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).